CPTAC case C3L-07611 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/60b6d64b-fc4c-4b52-9b65-287dc4db9c7d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1979; Vital status: Dead; Days to death: 348 days; Year of death: 2022; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Temporal lobe; Age at diagnosis: 41.9 years (15,303 days); Year of diagnosis: 2021; Last known disease status: With tumor; Days to last known disease status: 348 days; Progression or recurrence: no; Days to last follow up: 348 days.
   Pathology details: Greatest tumor dimension: 4.5 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Targeted Molecular Therapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (2 entries)
- Days to follow up: 342 days; Disease response: With Tumor.
- Days to follow up: 348 days; Disease response: With Tumor.

Other clinical attributes
- Weight: 132 kg; Height: 175.26 cm; BMI: 42.97.

Exposures
- Tobacco smoking status: Current Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-07611-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 83 mg; Time between excision and freezing: 30 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-07611-22: Section location: Temporal Lobe; Percent tumor nuclei: 85; Percent necrosis: 3.
- Sample C3L-07611-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 70 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-07611-23: Section location: Temporal Lobe; Percent tumor nuclei: 70; Percent necrosis: 3.
- Sample C3L-07611-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
